Somatic mutation profile of cancer-model specimen HCM-BROD-0225-C43-85M (Adherent Cell Line, passage 11; aliquot HCM-BROD-0225-C43-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0225-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 42.8 years (15,646 days).
Specimen HCM-BROD-0225-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 220820ed-7d43-485c-8803-a85e0d92bea4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0225-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0225-C43-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2bf7485-f528-4e86-b281-2303e46beb31

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GAT1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 20/626 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs891837806; called by muse, mutect2
- COBLL1 | c.974C>T p.S325L (on ENST00000392717; = p.S287L on NM_014900.5) | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776965929; called by muse, mutect2, varscan2
- CPNE4 | c.1605C>A p.Y535* | Nonsense Mutation (SNP) | VAF 165/370 reads (45%) | catalogued as rs1266437170; called by muse, mutect2, varscan2
- GABRR2 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 183/443 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs756735401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEBL | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 153/369 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs761425280, COSV65801472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCAL1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs774075396; called by muse, mutect2, varscan2
- ZNF629 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 153/354 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs534157296; called by muse, mutect2, varscan2
- ZNF700 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs143373214; called by muse, mutect2, varscan2
- DPP8 | c.209A>G p.K70R (on ENST00000341861 / NM_001320875.2; = p.K54R on NM_017743.6) | Missense Mutation (SNP) | VAF 19/417 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.061); called by muse, mutect2
- FRMD7 | c.303A>C p.Q101H | Missense Mutation (SNP) | VAF 104/123 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPKB | c.704C>A p.P235Q | Missense Mutation (SNP) | VAF 85/434 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MIEF2 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MUC16 | c.10897G>T p.G3633C | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PKD1L3 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.235); called by muse, mutect2
- PXMP4 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 23/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ADAMTS9 | c.1191C>T p.H397= | Silent (SNP) | VAF 164/375 reads (44%) | catalogued as rs773942814, COSV55790263; called by muse, mutect2, varscan2
- CACNA1E | c.73C>A p.R25= | Silent (SNP) | VAF 27/643 reads (4%) | catalogued as rs746663524; called by muse, mutect2
- ELOA2 | c.1824C>T p.Y608= | Silent (SNP) | VAF 150/353 reads (42%) | catalogued as rs267605191; called by muse, mutect2, varscan2
- HTR4 | c.465C>A p.L155= | Silent (SNP) | VAF 40/346 reads (12%) | called by muse, mutect2, varscan2
- PRODH2 | c.1578G>T p.R526= (on ENST00000301175; = p.R450= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 34/514 reads (7%) | called by muse, mutect2
- RAE1 | c.1107G>A p.*369= | Silent (SNP) | VAF 11/314 reads (4%) | called by muse, mutect2
- SYT15 | c.534G>A p.S178= | Silent (SNP) | VAF 93/615 reads (15%) | catalogued as rs561143478, COSV65431723; called by muse, mutect2, varscan2
- LDLR | c.2390-46C>G | Intron (SNP) | VAF 17/449 reads (4%) | called by muse, mutect2
